CCDI case PBBMPD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/040d879b-3c35-4f69-a441-289d6a559e32

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain stem; Age at diagnosis: 17.0 years (6,226 days).

Biospecimens (3 samples)
- Sample 0DCM15: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCM1D: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCM1I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
